Surgical pathology report (de-identified scan), TCGA case TCGA-UF-A7J9, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-UF-A7J9-01A (Primary Tumor).

ICD O-3
Carcinoma, squamous cell
NOS 8070/3
Site Larynx NOS C32.9
QJ 9/24/13

Collect date:

PATHOLOGY REPORT:

PRIMARY SITE: Larynx

- 1 - "Right supraglottic site biopsy":
- Invasive squamous cell carcinoma.
- 2 - "Larynx + neck dissection + right hemithyroidectomy":
- Invasive moderately differentiated squamous cell carcinoma.
- Tumor size: 3.0 x 2.4 x 1.0 cm.
- Tumor involves:
- Glottic, supraglottic and right infraglottic sites.
- Thyroid, cricoid and arytenoid cartilages.
- Right-posterior larynx adjacent soft tissue.
- Moderated stromal desmoplasia
- Perineural invasion: not identified.
- Vascular invasion: not identified.
- Lymphatic invasion: not identified.
- Left vocal cord and epiglottis uninvolved by neoplasia.
- Preepiglottic space uninvolved by neoplasia.
- Left thyroid gland exhibiting goiter.
- Surgical margins uninvolved by neoplasia.
- Fifteen lymph nodes uninvolved by neoplasia (0/15).
- 3 - "Right recurrential dissection":
- Three lymph nodes uninvolved by neoplasia (0/3).

Source: NCI Genomic Data Commons file e06bc346-fb02-4b31-bedb-60e9baa90865 (TCGA-UF-A7J9.942FA247-4EB6-44F4-B9A4-C111593CA728.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).